Somatic mutation profile of tumor specimen TCGA-S7-A7WW-01A (aliquot TCGA-S7-A7WW-01A-11D-A35I-08) from TCGA case TCGA-S7-A7WW, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 34.9 years (12,729 days).
Specimen TCGA-S7-A7WW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4957f2b-ecee-4ab4-b524-94c155bba78a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S7-A7WW-10B (Blood Derived Normal), aliquot TCGA-S7-A7WW-10B-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d1703d20-78d1-4e83-92f5-e07c6a93554f

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY6 | c.1850C>T p.A617V | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.593); catalogued as COSV100326415; called by muse, mutect2
- BARHL2 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs776330330, COSV64981391; called by muse, mutect2, varscan2
- KRT78 | c.408C>A p.N136K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPEF2 | c.1920+1G>A p.X640_splice | Splice Site (SNP) | VAF 38/106 reads (36%) | called by muse, mutect2, varscan2
- SLC27A6 | c.90C>A p.D30E | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ADAMTS20 | c.1056C>T p.D352= | Silent (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2
- FLAD1 | c.852A>G p.L284= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs756644101; called by muse, mutect2, varscan2
